Surgical pathology report (de-identified scan), TCGA case TCGA-QK-A8Z9, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Emory University - Winship Cancer Inst., specimen TCGA-QK-A8Z9-01B (Primary Tumor).

[page 1 of 6]
Document Type:
Document Date:
Document Status:
Document Title:
Performed By:
Verified By:
Encounter info:

100-3
Carcinoma, squamous cell NOS
Site Floor of mouth NOS
807013
C04.9
J 1/17/14

*** Final Report ***

(Verified)

Patient Name:

[REDACTED]

Acc #:

MRN:

[REDACTED]

DOB:

[REDACTED]

Location:

Gender:

M

Collected:

Client:

Received:

Submitting Phys:

Reported:

Copy To Phys:

Final Surgical Pathology Report

Final Pathologic Diagnosis

A. MANDIBULAR BONE WITH FLOOR OF MOUTH, VENTRAL TONGUE, LOWER LIP, MENTAL SKIN AND BILATERAL 1A/1B LYMPH NODES, COMPOSITE MANDIBULECTOMY:

- INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED (5.7 CM), WITH BONE INVOLVEMENT.
- SURGICAL MARGINS, NEGATIVE FOR CARCINOMA.
- PERINEURAL INVASION PRESENT.
- METASTATIC CARCINOMA INVOLVING ONE RIGHT LEVEL 1B LYMPH NODE OF TEN TOTAL NODES (1/10).
- SIZE OF METASTASIS: 2.5 MM.
- EXTRANODAL EXTENSION: NOT IDENTIFIED.
- ABUNDANT FILAMENTOUS ORGANISMS CONSISTENT WITH ACTINOMYCES IN MANDIBULAR BONE, ASSOCIATED WITH OSTEONECROSIS.
- SEE SYNOPTIC REPORT

B. INFERIOR ALVEOLAR NERVE, EXCISION #1:

- FOCAL SMALL PERIPHERAL NERVE, NEGATIVE FOR CARCINOMA.

C. INFERIOR ALVEOLAR NERVE, RIGHT, EXCISION #2:

- PERIPHERAL NERVE, NEGATIVE FOR CARCINOMA.

D. NECK, LEFT LEVEL 2, RESECTION:

- FOURTEEN BENIGN LYMPH NODES, NEGATIVE FOR CARCINOMA (0/14).

E. NECK, LEFT LEVEL 3, RESECTION:

- THIRTEEN BENIGN LYMPH NODES, NEGATIVE FOR CARCINOMA (0/13).

F. NECK, LEFT LEVEL 4, RESECTION:

- ELEVEN BENIGN LYMPH NODES, NEGATIVE FOR CARCINOMA (0/11).

G. NECK, LEFT LEVEL 5, RESECTION:

- TWO BENIGN LYMPH NODES, NEGATIVE FOR CARCINOMA (0/2).

[page 2 of 6]
H. NECK, RIGHT LEVEL 2, RESECTION:

- NINE BENIGN LYMPH NODES, NEGATIVE FOR CARCINOMA (0/9).

I. NECK, RIGHT LEVEL 3, RESECTION:

- THIRTEEN BENIGN LYMPH NODES, NEGATIVE FOR CARCINOMA (0/13).

J. NECK, RIGHT LEVEL 4, RESECTION:

- METASTATIC CARCINOMA INVOLVING ONE OF SEVEN LYMPH NODES (1/7).

- SIZE OF METASTASIS: 6.0 MM.

- EXTRANODAL EXTENSION: PRESENT.

K. NECK, RIGHT LEVEL 5, RESECTION:

- THREE BENIGN LYMPH NODES, NEGATIVE FOR CARCINOMA (0/3).

SEE SYNOPTIC REPORT

Electronically Signed by

Assisted by:

Synoptic Worksheet

A. Composite resection anterior mandible:

Clinical History:	No neoadjuvant therapy
Specimen:	Vermilion border lower lip Mucosa of lower lip Anterior two-thirds of tongue, NOS Lower gingiva (gum) Floor of mouth, NOS Lower vestibule of mouth Mandible Other: mental skin
Received:	In formalin
Procedure:	Mandibulectomy: Composite resection Neck (lymph node) dissection: Left levels 2-5. Right levels 3-5.
Specimen Integrity:	Intact
Specimen Size:	Greatest dimension: 9.9 cm Additional dimension: 9.4 cm Additional dimension: 7.7 cm
Specimen Laterality:	Bilateral
Tumor Site:	Floor of mouth, NOS
Tumor Focality:	Single focus
Tumor Size:	Greatest dimension: 5.7 cm Additional dimension: 5.3 cm Additional dimension: 1.9 cm
Tumor Description:	Ulcerated
Macroscopic Extent of Tumor:	Invades lower lip, floor of mouth, mandible, skin of face, tongue.
Histologic Type:	Squamous cell carcinoma, conventional
Histologic Grade:	G2: Moderately differentiated
Margins:	Margins uninvolved by invasive carcinoma
Lymph-Vascular Invasion:	Present
Perineural Invasion:	Present
Lymph Nodes, Extranodal Extension:	Present
Pathologic Staging (pTNM):	

[page 3 of 6]
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT4a: Moderately advanced local disease. Lip: Tumor invades through cortical bone, inferior alveolar nerve, floor of mouth, or skin of face, ie, chin or nose. Oral cavity: Tumor invades adjacent structures only
Regional Lymph Nodes (pN):	pN2b: Metastasis in multiple ipsilateral lymph nodes, none more than 6 cm in greatest dimension Number of regional lymph nodes examined: 82 Number of regional lymph nodes involved: 2
Distant Metastasis (pM):	Not applicable

Clinical History

Mouth cancer. Bilateral neck dissection.

Specimen(s) Received

A: Composite resection anterior mandible
B: Inferior alveolar nerve
C: Right inferior alveolar nerve, ink - true margin
D: Left neck level 2
E: Left neck level 3
F: Left neck level 4
G: Left neck level 5
H: Right neck level 2
I: Right neck level 3
J: Right neck level 4
K: Right neck level 5

Gross Description

Specimen A is received in formalin, labeled with the patient's name, medical record number and as "composite resection, anterior mandible." The specimen consists of a subtotal mandibulectomy, from right cricoid to the left body of mandible. There are two left premolar teeth and one canine tooth present. The entire specimen measures 9.9 x 9.4 x 7.7 cm. There is skin present on the anterior surface, measuring 11.4 x 9.5 cm. There is an attached portion of tongue measuring 5.9 x 5.7 x 3.1 cm. There is a large tan-gray, necrotic ulcer in the skin, measuring 6.2 x 4.5 cm. There is a large irregular, necrotic lesion in the floor of the mouth that extends from the skin ulcer, this lesion measures 5.7 x 5.3 x 1.9 cm (sagittal section). The lesion from base of tongue to the inferior edge of the skin ulcer measures 7.7 cm. There is a pathologic fracture of the anterior mandible. All remaining soft tissues are inked black (true margin). Yellow ink designates 'not true margin'. Representative sections are submitted as described in the cassette summary. Dictated by

CASSETTE SUMMARY:

A1FS – right posterior/tonsil
A2FS – right tongue (orange = split)
A3FS – left tongue (orange = split)
A4FS – left lingual vestibule/floor of mouth
A5FS – left posterior ridge, mucosa
A6FS – left buccal mucosa
A7FS – left facial skin (lateral)
A8FS – left/inferior skin
A9FS – right/inferior skin
A10FS – right facial skin (lateral)
A11FS – right facial skin to commissure
A12FS – right lip and buccal vestibule (orange = split)
A13 – posterior soft tissue
A14 – right soft tissue
A15 – left soft tissue
A16 – inferior soft tissue, level 1A

[page 4 of 6]
A17 – white nodule and adipose tissue in level 1A area
A18 – tumor in mandible (decalcified)
A19 – left ulcer, skin
A20 – superior ulcer, skin
A21 – inferior ulcer, skin
A22 – tumor in relation to lower lip
A23 – tumor in relation to tongue
A24 – tumor in relation to floor of mouth
A25 – right submandibular gland
A26 – right level 1B, one lymph node, bisected
A27 – right level 1B, one lymph node, bisected
A28 – right level 1B, one lymph node
A29 – left submandibular gland
A30 – left level 1B, one lymph node, bisected
A31 – left level 1B, one lymph node
A32 – left level 1B, two lymph nodes
A33 – right mandible bone margin (decalcified)
A34 – left mandible bone margin (decalcified)
A35 – tumor in bone (decalcified)
A36 – tumor in bone (decalcified)

Specimen B is labeled "inferior alveolar nerve." The specimen consists of a tan fragment of tissue measuring 1.4 x 0.4 x 0.1 cm. The specimen is submitted entirely in cassette "B1FS." Dictated by

Specimen C is received fresh, labeled with the patient's name, medical record number and as "right inferior alveolar nerve." The specimen consists of a fragment of tan tissue measuring 1.2 x 0.4 x 0.2 cm. The true margin is inked. The entire specimen is submitted in cassette "C1FS." Dictated by

Specimen D is received in formalin, labeled with the patient's name, medical record number and as "left neck level 3." The specimen consists of a portion of fibroadipose tissue measuring 4.5 x 3.5 x 2.9 cm. Representative sections contain possible lymph node and submitted as described in the cassette summary. Dictated by

CASSETTE SUMMARY:

D1 – two possible lymph nodes
D2 – three possible lymph nodes
D3 – three possible lymph nodes
D4 – representative section of fat

Specimen E is received in formalin, labeled with the patient's name, medical record number and as "left neck level 3." The specimen consists of a fragment of soft tissue with attached adipose, measuring 5.5 x 4.4 x 1.2 cm. Dictated by

CASSETTE SUMMARY:

E1 – one lymph node, bisected
E2 – one lymph node, bisected
E3 – three possible lymph nodes
E4 – three possible lymph nodes
E5 – three possible lymph nodes

Specimen F is received in formalin, labeled with the patient's name, medical record number and as "left neck level 4." The specimen consists of a fragment of soft tissue with attached adipose, measuring 6.5 x 5.0 x 1.2 cm. Representative sections of the possible lymph nodes are submitted as described in the cassette summary. Dictated by

CASSETTE SUMMARY:

F1 – two possible lymph nodes
F2 – two possible lymph nodes
F3 – two possible lymph nodes

[page 5 of 6]
Specimen G is received in formalin, labeled with the patient's name, medical record number and as "left neck level 5." The specimen consists of a portion of fibroadipose tissue measuring 4.1 x 2.9 x 0.8 cm. Representative sections of possible lymph nodes are submitted as described in the cassette summary. Dictated by

CASSETTE SUMMARY:

G1 – one possible lymph node
G2 – representative fat

Specimen H is received in formalin, labeled with the patient's name, medical record number and as "right level 2." The specimen consists of a fragment of fibroadipose tissue measuring 4.6 x 3.7 x 1.1 cm. Representative sections containing possible lymph nodes are submitted as described in the cassette summary. Dictated by

CASSETTE SUMMARY:

H1 – three possible lymph nodes
H2 – two possible lymph nodes

Specimen I is received in formalin, labeled with the patient's name, medical record number and as "right level 3." The specimen consists of a portion of fibroadipose tissue measuring 5.3 x 4.0 x 2.1 cm. Representative sections containing lymph nodes are submitted as described in the cassette summary. Dictated by

CASSETTE SUMMARY:

I1 – two possible lymph nodes
I2 – three possible lymph nodes
I3 – two possible lymph nodes

Specimen J is received in formalin, labeled with the patient's name, medical record number and as "right level 4." The specimen consists of a fragment of fibroadipose tissue measuring 7.0 x 3.3 x 1.5 cm. Dictated by

CASSETTE SUMMARY:

J1 – two possible lymph nodes
J2 – two possible lymph nodes
J3 – one lymph node

Specimen K is received in formalin, labeled with the patient's name, medical record number and as "right level 5." The specimen consists of a fragment of fibroadipose tissue measuring 5.9 x 2.5 x 0.9 cm. Representative sections with possible lymph nodes are submitted as described in the cassette summary. Dictated by

CASSETTE SUMMARY:

K1 – three possible lymph nodes

Intraoperative Consult Diagnosis

A1FS-A12FS: COMPOSITE RESECTION ANTERIOR MANDIBLE, (FROZEN SECTION): NEGATIVE FOR
INVASIVE CARCINOMA. 360 DEGREES mucosal and SKIN SHAVE margins.
B1FS: INFERIOR ALVEOLAR NERVE, (FROZEN SECTION): NEGATIVE FOR CARCINOMA.
Frozen section results were communicated to the surgical team and were repeated back by
on
C1FS: RIGHT INFERIOR ALVEOLAR NERVE, (FROZEN SECTION): NEGATIVE FOR CARCINOMA.

[page 6 of 6]
Frozen section results were communicated to the surgical team and were repeated back by

Pathologist:

Source: NCI Genomic Data Commons file b4629a8b-67e5-4bb3-bd5d-47fdb56a8b76 (TCGA-QK-A8Z9.98CBE86B-44CA-46FB-AD91-CB5BCAEF2D61.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).